Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0U5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0U5-01A (Primary Tumor).

[page 1 of 2]
Diagnostic Discrepancy		/

Surgical Pathology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

Physician(s): [REDACTED]

cc:

Client: [REDACTED]

Location: [REDACTED]

1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1 w 5/1/11

History/Clinical Dx: Endometrial cancer

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

- A: Uterus, cervix, tubes and ovaries
- B: Left pelvic lymph node
- C: Left aortic lymph node
- D: Right pelvic lymph node
- E: Right common lymph node
- F: Right caval lymph node

DIAGNOSIS:

A. Uterus, cervix, tubes and ovaries:

ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:	TAH-BSO with lymph node sampling
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 1
Nuclear grade:	2
Extent of invasion:	No myometrial invasion
Lympho/vascular invasion:	Not identified
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical involvement:	Absent
Right adnexa:	No evidence of tumor
Left adnexa:	No evidence of tumor
Staging:	Stage IA (T1a, N0)

B. Left pelvic lymph nodes:

Five (5) lymph nodes negative for metastasis

C. Left aortic lymph node:

Fibrovascular tissue with no lymph node identified

D. Right pelvic lymph nodes:

Three (3) lymph nodes negative for metastasis

E. Right common lymph node:

Two (2) lymph nodes negative for metastasis

F. Right caval lymph node:

One (1) lymph node negative for metastasis

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing the above report. This test was developed and its performance characteristics determined by [REDACTED] It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Surgical Pathology Report

Gross Description

- A. Submitted as "uterus, cervix, bilateral tubes and ovaries" is a uterus with attached cervix and bilateral tubes and ovaries weighing 178 grams. The body of the uterus measures 9.5 x 5.0 x 4.0 cm in greatest dimension. The serosal surface is smooth. The ectocervical mucosa is smooth. The endocervical canal contains a firm nodular lesion in the upper endocervical canal, which also involves the lower uterine segment. The nodule is on the posterior endocervical wall. Sectioning through this nodule shows a partly cystic gross appearance with no obvious infiltrative component. The endometrial cavity is lined by shaggy mucosa, which in the superior fundus is papillary. In this area the papillary mass measures 2.8 x 2.0 cm and is raised above the surface 0.8 cm. Sectioning through the endometrial lesions show equivocal early invasion of the underlying myometrium. In this area, the myometrium measures 1.0 cm in thickness and the gross invasion measures < 1.0 mm. The myometrium contains no other lesions. The right tube measures 3.5 cm in length and up to 0.5 cm in diameter. The right ovary measures 2.1 x 0.9 x 0.5 cm and is grossly unremarkable. The left tube measures approximately 5.0 cm in length. There are prominent adhesions to the adjacent ovary, which measures approximately 2.0 x 1.1 x 0.8 cm in greatest dimension.

KEY TO CASSETTES:

A1-A2	Cervix
A3-A4	Endocervical nodule
A5-A7	Full thickness sections the endometrial lesion
A8-A10	Additional sections of the endometrial lesion
A11	Parametrium
A12	Right tube and ovary
A13	Left tube and ovary

- B. Submitted as "left pelvic lymph nodes" are several fragments of fatty tissue.

KEY TO CASSETTES:

B1-B2	One lymph node serially sectioned
B3	One lymph node bisected
B4	Individual nodes

- C. Submitted as "left aortic lymph node biopsy" is a single piece of hemorrhagic tan tissue measuring 1.5 cm in greatest dimensions. It is entirely submitted in one cassette.

- D. Submitted as "right pelvic lymph nodes" are multiple fragments of hemorrhagic fatty tissue weighing 5 grams in aggregate.

KEY TO CASSETTES:

D1-D2	Single lymph node serially sectioned
D3	Single lymph node bisected
D4	Individual nodes

- E. Submitted as "right common lymph node biopsy" is a single piece of hemorrhagic fatty tissue measuring 1.1 cm in greatest dimensions. It is entirely submitted in one cassette.

- F. Submitted as "right caval lymph node" is a single piece of hemorrhagic fatty tissue measuring 1.4 cm in greatest dimension. It is bisected and entirely submitted in one cassette.

Microscopic Description

The microscopic findings support the above diagnosis.

Source: NCI Genomic Data Commons file d5333850-1c03-4f48-b048-f8ab265a10aa (TCGA-BS-A0U5.8024498D-449C-45C6-B57D-846DDBA3FF30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).